Gene-level copy-number profile of tumor specimen HTMCP-03-06-02109-01B from CGCI case HTMCP-03-06-02109, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2.
Specimen HTMCP-03-06-02109-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file efa3690a-0116-4b1d-84ba-6631926d603b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02109-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/9f77858e-4f10-49f6-ac3d-f58b7ac24c1a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 1,225; copy number 2: 16,193; copy number 3: 22,949; copy number 4: 12,016; copy number 5: 4,256; copy number 6: 1,613; copy number 7: 32; copy number 8: 31; copy number 10: 4; copy number 11: 2; copy number 12: 28; copy number 13: 1; copy number 15: 1; copy number 16: 2; copy number 19: 2; copy number 20: 1; copy number 43: 4; copy number 79: 3; copy number 305: 1.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:36,165,681–36,439,566, 14 genes (within-gene range 0–3): TBC1D3B, AC243829.1, CCL3L3, CCL4L2, AC243829.5, AC243829.3, AC243829.6, TBC1D3I, AC233699.1, Y_RNA, TBC1D3G, TBC1D3H, RNU6-1192P, TBC1D3F.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 112 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:119,146,151–119,240,946, 4 genes, copy number 11–305 (within-gene range 6–305): TEX55, AC083800.1, UPK1B, B4GALT4.
- chr3:189,631,389–190,322,446, 9 genes, copy number 7: TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1.
- chr5:23,329,427–23,329,892, 1 gene, copy number 13: AC010460.1.
- chr7:38,239,580–38,249,572, 1 gene, copy number 7: TRGC2.
- chr7:38,256,337–38,340,998, 15 genes, copy number 7: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr8:43,672,823–43,674,591, 2 genes, copy number 7: AC139365.2, AC139365.1.
- chr9:65,189,995–65,250,826, 2 genes, copy number 11–15: BMS1P12, IGKV1OR9-1.
- chr11:47,239,302–47,269,033, 2 genes, copy number 7: ACP2, NR1H3.
- chr11:123,358,428–123,627,774, 1 gene, copy number 8 (within-gene range 2–8): GRAMD1B.
- chr12:52,069,246–52,108,261, 5 genes, copy number 8–43: ATG101, AC025259.1, SMIM41, OR7E47P, AC078864.1.
- chr14:21,924,063–22,482,959, 59 genes, copy number 7–12 (within-gene range 5–12): TRAV14DV4, TRAV9-2, TRAV15, AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54.
- chr14:22,547,506–22,552,156, 1 gene, copy number 12: TRAC.
- chr15:21,911,559–21,951,323, 3 genes, copy number 19–20: ZNF519P3, NF1P2, MIR5701-3.
- chr17:39,637,090–39,730,532, 7 genes, copy number 10–79: STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1.

Autosomal genes at a single copy (total copy number 1): 1,225. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
